FM case AD4372 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/a51d6a4d-d9b7-4a7a-9506-c1c86fb39c2c

Female, 69.8 years: Adenoid cystic carcinoma (ICD-O-3 8200/3) of the breast; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
